Somatic mutation profile of tumor specimen TCGA-WB-A80L-01A (aliquot TCGA-WB-A80L-01A-11D-A35I-08) from TCGA case TCGA-WB-A80L, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 30.1 years (10,980 days).
Specimen TCGA-WB-A80L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a8774db-4439-46cf-b871-173aa2f4f901.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A80L-10A (Blood Derived Normal), aliquot TCGA-WB-A80L-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57110aa5-c1b1-4f58-96b4-b4f9b35f8a48

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPARGC1A | c.879C>A p.G293= | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as rs1440331346; called by muse, mutect2
